Gene-level copy-number profile of tumor specimen TCGA-AR-A24S-01A from TCGA case TCGA-AR-A24S, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 61.8 years (22,587 days).
Specimen TCGA-AR-A24S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.ce2bf11c-61cb-49c7-8135-906719050d28.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A24S-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e87863d9-e00a-44d8-8331-bb9214b5554a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,035; copy number 2: 13,878; copy number 3: 14,387; copy number 4: 24,235; copy number 5: 2,808; copy number 6: 958; copy number 7: 295; copy number 8: 1,675; copy number 9: 189; copy number 10: 200; copy number 12: 104; copy number 14: 54.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A24S-01A-11D-A166-01): tumor purity 0.46, ploidy 3.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 547 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:12,833,951–15,419,141, 126 genes, copy number 10–14 (within-gene range 6–14) (broad region; genes not listed).
- chr19:17,747,718–21,064,261, 169 genes, copy number 9 (broad region; genes not listed).
- chr20:2,835,314–6,220,759, 104 genes, copy number 12 (broad region; genes not listed).
- chr20:9,537,370–18,381,484, 128 genes, copy number 10 (broad region; genes not listed).
- chr20:19,208,652–20,712,644, 20 genes, copy number 9 (within-gene range 6–9): AL136090.2, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1, RALGAPA2, EIF4E2P1.

Autosomal genes at a single copy (total copy number 1): 1,035. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
